Somatic mutation profile of tumor specimen TCGA-EM-A3AI-01A (aliquot TCGA-EM-A3AI-01A-11D-A202-08) from TCGA case TCGA-EM-A3AI, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 68.0 years (24,820 days).
Specimen TCGA-EM-A3AI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) babe59d5-7650-44c5-b5d4-447ae689d03d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3AI-10A (Blood Derived Normal), aliquot TCGA-EM-A3AI-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/444bebd8-1e9b-4e52-9f95-210c339df09d

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRD1 | c.967-1G>C p.X323_splice | Splice Site (SNP) | VAF 31/137 reads (23%) | catalogued as COSV55443987, COSV55456936; called by muse, mutect2, varscan2
- CSMD3 | c.4600C>T p.P1534S (on ENST00000297405 / NM_001363185.1; = p.P1430S on NM_052900.3) | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV52303526, COSV52314954; called by muse, mutect2
- ELL | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs748628873, COSV53215893; called by muse, mutect2, varscan2
- GPX8 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.02); catalogued as COSV57057357; called by muse, mutect2, varscan2
- GRIK1 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.511); catalogued as rs780322333, COSV58731658; called by muse, mutect2, varscan2
- NEDD4L | c.896G>T p.G299V | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV56853223; called by muse, mutect2
- PI4K2B | c.1027A>G p.I343V | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749434996, COSV53513008; called by muse, mutect2, varscan2
- PRPF6 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 144/617 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.178); catalogued as COSV53878505; called by muse, mutect2, varscan2
- SPATA25 | c.211A>G p.R71G | Missense Mutation (SNP) | VAF 82/330 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV51944872; called by muse, mutect2, varscan2
- TG | c.490T>G p.C164G | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55093701; called by muse, mutect2, varscan2
- EFNB3 | c.900C>T p.G300= | Silent (SNP) | VAF 18/118 reads (15%) | catalogued as rs528034465, COSV56832863; called by muse, mutect2, varscan2
